Somatic mutation profile of tumor specimen TCGA-WY-A85B-01A (aliquot TCGA-WY-A85B-01A-11D-A36O-08) from TCGA case TCGA-WY-A85B, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 24.1 years (8,817 days).
Specimen TCGA-WY-A85B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7efa260b-0059-4c08-bdee-b015349b689d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A85B-10A (Blood Derived Normal), aliquot TCGA-WY-A85B-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5d31cd1-323d-4b34-be29-64a6aa1c846c

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 34/91 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/23 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.1357A>G p.N453D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101187786; called by muse, mutect2
- ATRX | c.6217G>A p.G2073S | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100970095; called by muse, mutect2, varscan2
- C8orf34 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100444475, COSV61380867; called by muse, mutect2, varscan2
- CDO1 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99164751; called by muse, mutect2, varscan2
- HNRNPCL1 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 19/379 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.84); catalogued as COSV100508799; called by muse, mutect2
- KCNA4 | c.882G>C p.W294C | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068553; called by muse, mutect2
- MMRN1 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV99306477; called by muse, mutect2
- PPM1F | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775666012, COSV99601276; called by muse, mutect2, varscan2
- RAI1 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs754955930, COSV55389598; ClinVar: uncertain significance; called by muse, mutect2
- CD86 | c.901dup p.I301Nfs*5 (on ENST00000330540 / NM_175862.5; = p.I295Nfs*5 on NM_006889.4) | Frame Shift Ins (INS) | VAF 31/88 reads (35%) | called by mutect2, pindel, varscan2
- OR51T1 | c.636C>T p.D212= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs138268565; called by muse, mutect2
